Surgical pathology report (de-identified scan), TCGA case TCGA-E7-A97P, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Asterand, specimen TCGA-E7-A97P-01A (Primary Tumor).

[page 1 of 2]
TSS Patient ID:

Surgical Date:

Gross Description: In bladder, it is invasive and protruded masse, ill - margins with 5x4x4cm in size, soft and gray surface.

Microscopic Description: Tumor cells are hyperplastic to form nest or groups or cords or tubules. Tumor cells have moderate and eosinophilic or clear cytoplasm. Nuclei are very enlarged and varriability in shape and size, irregular nuclear membranes, nucleoli and abnormal chromatin patterns. Mitoses are present. Tumor invades in muscle propria or nerves.

Diagnosis Details: Infiltrating urothelial carcinoma, high-grade, infiltrating muscularis propria

Comments:

Formatted Path Reports: BLADDER TISSUE CHECKLIST

Specimen type: Cystectomy

Tumor site: Bladder (Per TSS, site is bladder wall.)

Tumor size: 5 x 4 x 4 cm

Tumor features: None specified

Histologic type: Transitional cell carcinoma

Histologic grade: Poorly differentiated

Tumor extent: Muscularis propria

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: No

Additional pathologic findings: Extracapsular extension: present, focal

Comments: None

CLUE ICD-O-3
Carcinoma, urothelial NOS
8/20/13
path Carcinoma, transitional cell NOS
8/20/13
Date Bladder wall NOS
6/6/14
JAD 4/7/14

Tumor site determined by TSS to be bladder wall. See dx discrepancy form.

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Transitional cell carcinoma	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Muscle invasive	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Specific location of tumor within the bladder was not given in path report, but was given on CQCF with the tumor being located on the wall of the bladder.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 9a3659d2-f086-49fb-abb3-4ab314af4a34 (TCGA-E7-A97P.F93869FD-9F81-4BB1-B0A4-489E5293C31F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).